Somatic mutation profile of tumor specimen TCGA-OR-A5KY-01A (aliquot TCGA-OR-A5KY-01A-11D-A29I-10) from TCGA case TCGA-OR-A5KY, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 23.9 years (8,745 days).
Specimen TCGA-OR-A5KY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa92859d-dc60-41d6-b998-1e0377d9e609.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KY-10A (Blood Derived Normal), aliquot TCGA-OR-A5KY-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/343784f5-c79f-4a39-a13e-5869c6d8325a

The open-access MAF lists 31 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 4, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEN1 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 67/91 reads (74%) | catalogued as rs1060499974, CD148208, CD982775, CM970937, COSV53641032; ClinVar: pathogenic; called by muse, mutect2
- ANXA8 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 185/1251 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1427838234; called by muse, mutect2, varscan2
- ARGFX | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 109/285 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV57683775; called by muse, mutect2, varscan2
- CCDC125 | c.648G>C p.E216D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as COSV101143677; called by muse, mutect2, varscan2
- CD1A | c.177C>A p.S59R | Missense Mutation (SNP) | VAF 118/173 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs559573053; called by muse, mutect2, varscan2
- DNAH11 | c.7699G>T p.G2567* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV60984443; called by muse, mutect2, varscan2
- FCRL5 | c.2239G>T p.V747F | Missense Mutation (SNP) | VAF 102/287 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV62519218; called by muse, mutect2, varscan2
- FRMD4B | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101273351; called by muse, mutect2, varscan2
- H2AC11 | c.225G>C p.K75N | Missense Mutation (SNP) | VAF 191/274 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV60362192; called by muse, mutect2, varscan2
- KIAA1522 | c.677G>C p.G226A (on ENST00000373480 / NM_001198972.2; = p.G285A on NM_020888.3) | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV53863487; called by muse, mutect2, varscan2
- DNAJC9 | c.191_192del p.K64Sfs*7 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- EXD1 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 82/120 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FTO | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- GABRA6 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GPR142 | c.1226C>G p.A409G | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- HYAL4 | c.1208C>A p.A403E | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IGKV2D-28 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by mutect2, varscan2
- MUC16 | c.29121C>A p.S9707R | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- NTRK3 | c.1202C>A p.P401Q | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PCDHB3 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); called by muse, mutect2
- POTED | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 54/110 reads (49%) | called by muse, mutect2, varscan2
- SLC44A4 | c.332C>G p.P111R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- ZC3H13 | c.3697A>T p.R1233* | Nonsense Mutation (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- ZNRF3 | c.572_588del p.L191Qfs*19 (on ENST00000544604 / NM_001206998.2; = p.L91Qfs*19 on NM_032173.3) | Frame Shift Del (DEL) | VAF 31/52 reads (60%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.1548G>A p.P516= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs199528626; called by muse, mutect2, varscan2
- GABRA6 | c.105C>A p.I35= | Silent (SNP) | VAF 36/179 reads (20%) | catalogued as COSV99194263; called by muse, varscan2
- KCNJ14 | c.237C>G p.T79= | Silent (SNP) | VAF 62/295 reads (21%) | called by muse, mutect2, varscan2
- PLAC9 | c.219G>C p.L73= | Silent (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- RASGRP4 | c.1065C>G p.L355= | Silent (SNP) | VAF 16/280 reads (6%) | catalogued as rs758322359, COSV99498539; called by muse, mutect2
- SSTR1 | c.717C>A p.I239= | Silent (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- ZNF555 | c.1581G>C p.V527= | Silent (SNP) | VAF 38/149 reads (26%) | catalogued as COSV62073175; called by muse, mutect2, varscan2
